PECGS case C083-000052 — USC PE-CGS: Optimizing Engagement of Hispanic Colorectal Cancer Patients in Cancer Genomic Characterization Studies (PECGS-COPECC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Rectum.
https://portal.gdc.cancer.gov/cases/7b664c37-5206-4e01-bfa5-fd96b310a75b

Demographics
Sex at birth: male; Race: white; Ethnicity: hispanic or latino; Age at index: 37 years; Year of birth: 1985; Vital status: Dead; Education level: Vocational College or Some College.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Rectum, NOS; Age at diagnosis: 36.7 years (13,405 days); AJCC clinical stage: Stage IVA; AJCC pathologic stage: Stage IVA; Progression or recurrence: no.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Pack years smoked: 0.

Biospecimens (2 samples)
- Sample C083-000052_Germline: Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample C083-000052_Tumor: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
